Somatic mutation profile of tumor specimen TCGA-FU-A3TQ-01A (aliquot TCGA-FU-A3TQ-01A-11D-A22X-09) from TCGA case TCGA-FU-A3TQ, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 55.6 years (20,302 days).
Specimen TCGA-FU-A3TQ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4540f3fd-a376-41ea-bd4b-c41821748b5f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FU-A3TQ-10A (Blood Derived Normal), aliquot TCGA-FU-A3TQ-10A-01D-A22X-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a5fe79bb-e179-40b9-ad21-ab4df3c1dbfb

The open-access MAF lists 70 somatic variants for this specimen: 50 protein-altering or splice-affecting, 20 silent.
By variant classification: Missense Mutation 41, Silent 20, Splice Site 4, Nonsense Mutation 3, Frame Shift Ins 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MAPK1 | c.964G>A p.E322K | Missense Mutation (SNP) | VAF 28/56 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1057519911, COSV53184855, COSV99308005; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ACTL6A | c.121A>G p.I41V | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs748257527, COSV66998723; called by muse, mutect2, varscan2
- AGAP1 | c.401C>A p.A134D | Missense Mutation (SNP) | VAF 34/105 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58318561; called by muse, mutect2, varscan2
- ATR | c.3262C>G p.Q1088E | Missense Mutation (SNP) | VAF 20/55 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0.062); catalogued as COSV63384487; called by muse, mutect2, varscan2
- CEND1 | c.401C>A p.A134E | Missense Mutation (SNP) | VAF 3/33 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV100204171; called by muse, mutect2
- DHPS | c.800A>G p.N267S | Missense Mutation (SNP) | VAF 20/63 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV52951629; called by muse, mutect2, varscan2
- DLGAP3 | c.217C>T p.P73S | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT tolerated, low confidence (0.16); PolyPhen probably damaging (0.92); catalogued as COSV52391885; called by muse, mutect2, varscan2
- DOP1B | c.1792C>G p.P598A | Missense Mutation (SNP) | VAF 16/56 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.729); catalogued as rs1316898570, COSV67692304; called by muse, mutect2, varscan2
- DZANK1 | c.28C>G p.Q10E | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.147); catalogued as COSV52748094, COSV99362201; called by muse, mutect2
- ENPP3 | c.893G>T p.R298M | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62953178; called by muse, mutect2, varscan2
- EP300 | c.3671+1G>A p.X1224_splice | Splice Site (SNP) | VAF 21/63 reads (33%) | catalogued as COSV54327591, COSV99607896; called by muse, mutect2, varscan2
- FAT2 | c.1066A>C p.K356Q | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs931394739, COSV55814540; called by muse, mutect2, varscan2
- GATB | c.1141C>T p.R381* | Nonsense Mutation (SNP) | VAF 15/42 reads (36%) | catalogued as rs371263176; called by muse, mutect2, varscan2
- H6PD | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT tolerated (0.25); PolyPhen benign (0.141); catalogued as rs565031451, COSV66230385; called by muse, mutect2, varscan2
- HLA-B | c.896-1G>C p.X299_splice | Splice Site (SNP) | VAF 28/99 reads (28%) | catalogued as COSV69520575, COSV69520821; called by muse, mutect2
- KRT6A | c.1502G>A p.S501N | Missense Mutation (SNP) | VAF 14/96 reads (15%) | SIFT tolerated (0.39); PolyPhen benign (0.035); catalogued as COSV58104004; called by muse, mutect2, varscan2
- LFNG | c.511G>T p.A171S (on ENST00000222725 / NM_001040167.2; = p.A42S on NM_002304.2) | Missense Mutation (SNP) | VAF 36/100 reads (36%) | SIFT tolerated (0.19); PolyPhen benign (0.107); catalogued as COSV56068745, COSV99761596; called by muse, mutect2, varscan2
- MAGEC3 | c.448A>G p.T150A | Missense Mutation (SNP) | VAF 35/94 reads (37%) | SIFT tolerated, low confidence (0.61); PolyPhen benign (0); catalogued as COSV53576786; called by muse, mutect2
- MED12 | c.1861C>T p.R621* | Nonsense Mutation (SNP) | VAF 20/66 reads (30%) | catalogued as COSV61333117; called by muse, mutect2, varscan2
- MIOS | c.2056G>A p.D686N | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0.019); catalogued as COSV60767218; called by muse, mutect2, varscan2
- MTHFD2L | c.703C>T p.R235W (on ENST00000395759 / NM_001144978.2; = p.R177W on NM_001004346.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); catalogued as rs775868972, COSV57466157; called by muse, mutect2, varscan2
- NEGR1 | c.392T>C p.V131A | Missense Mutation (SNP) | VAF 19/83 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV60832465; called by muse, mutect2, varscan2
- NR0B1 | c.688C>T p.R230W | Missense Mutation (SNP) | VAF 8/29 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.571); catalogued as COSV66763665; called by muse, mutect2, varscan2
- NR3C2 | c.2799+1G>A p.X933_splice | Splice Site (SNP) | VAF 26/80 reads (33%) | catalogued as CS070397, COSV60986028; called by muse, mutect2, varscan2
- OR11H12 | c.155T>G p.L52R | Missense Mutation (SNP) | VAF 50/105 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); catalogued as COSV73543491; called by muse, mutect2, varscan2
- OR51A4 | c.936G>T p.K312N | Missense Mutation (SNP) | VAF 31/136 reads (23%) | SIFT tolerated (0.05); PolyPhen benign (0.051); catalogued as COSV66749137; called by muse, mutect2, varscan2
- PCDHA7 | c.2156C>T p.T719M | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.1); catalogued as COSV100970845, COSV65335104; called by muse, mutect2, varscan2
- PCDHB1 | c.28C>G p.Q10E | Missense Mutation (SNP) | VAF 30/80 reads (38%) | SIFT tolerated (0.16); PolyPhen benign (0.025); catalogued as COSV60629683; called by muse, mutect2, varscan2
- PDE1C | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 25/68 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs765961590, COSV58504744; called by muse, mutect2, varscan2
- PTEN | c.43A>T p.R15* | Nonsense Mutation (SNP) | VAF 26/55 reads (47%) | catalogued as CD144073, COSV64290996, COSV64304277; called by muse, mutect2, varscan2
- RUNX1 | c.1199G>A p.R400H (on ENST00000344691 / NM_001001890.3; = p.R427H on NM_001754.5) | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV55868690; called by muse, mutect2, varscan2
- SET | c.171-1G>C p.X57_splice (on ENST00000372692 / NM_001374326.1; = p.X44_splice on NM_003011.4) | Splice Site (SNP) | VAF 13/46 reads (28%) | catalogued as COSV59001188; called by muse, mutect2, varscan2
- SIPA1L3 | c.3922G>T p.D1308Y | Missense Mutation (SNP) | VAF 31/117 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV55909618; called by muse, mutect2, varscan2
- SLAMF9 | c.578A>G p.D193G | Missense Mutation (SNP) | VAF 20/66 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV63636338; called by muse, mutect2, varscan2
- SLC17A3 | c.475T>C p.F159L | Missense Mutation (SNP) | VAF 9/48 reads (19%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.617); catalogued as COSV57759559; called by muse, mutect2, varscan2
- SLC45A3 | c.1624G>A p.V542I | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.159); catalogued as COSV65654653; called by muse, mutect2, varscan2
- SPAG16 | c.1309C>T p.R437C | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.417); catalogued as rs142357329; called by muse, mutect2, varscan2
- SPATA31E1 | c.400C>T p.R134W | Missense Mutation (SNP) | VAF 16/50 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.116); catalogued as rs755167389, COSV57789803; called by muse, mutect2, varscan2
- SRSF9 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 20/67 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV57570074; called by muse, mutect2, varscan2
- STAC | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 22/71 reads (31%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV56207226, COSV56208140; called by muse, mutect2, varscan2
- TBC1D2B | c.1097G>A p.R366Q | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.05); PolyPhen benign (0.007); catalogued as rs201555902, COSV56038773; called by muse, mutect2, varscan2
- TLN1 | c.2245G>A p.G749S | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.005); catalogued as rs746904145, COSV59204700; called by muse, mutect2, varscan2
- UIMC1 | c.977C>G p.P326R | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65893183; called by muse, mutect2, varscan2
- XYLB | c.560A>T p.Y187F | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.582); catalogued as COSV52911810; called by muse, mutect2, varscan2
- ZC3H18 | c.1061G>A p.R354Q | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.67); catalogued as rs267604676, COSV56323107; called by muse, mutect2, varscan2
- ZFYVE26 | c.4693G>C p.E1565Q | Missense Mutation (SNP) | VAF 25/87 reads (29%) | SIFT tolerated (0.37); PolyPhen benign (0.438); catalogued as COSV61325070; called by muse, mutect2, varscan2
- ZNF318 | c.2771G>T p.G924V | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV58930547; called by muse, mutect2, varscan2
- CELSR1 | c.4576_4577insCA p.R1526Pfs*33 | Frame Shift Ins (INS) | VAF 7/25 reads (28%) | called by mutect2, pindel, varscan2
- CSAG2 | c.97C>T p.R33C | Missense Mutation (SNP) | VAF 38/78 reads (49%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.123); called by mutect2, varscan2
- ZNF750 | c.753dup p.L252Afs*16 | Frame Shift Ins (INS) | VAF 22/58 reads (38%) | called by mutect2, pindel, varscan2
- AGMAT | c.759G>A p.K253= | Silent (SNP) | VAF 27/100 reads (27%) | catalogued as rs149178480; called by muse, mutect2
- AP1B1 | c.2397G>A p.T799= | Silent (SNP) | VAF 18/54 reads (33%) | catalogued as rs757462238, COSV58014958; called by muse, mutect2, varscan2
- CASZ1 | c.738C>T p.L246= | Silent (SNP) | VAF 21/68 reads (31%) | catalogued as COSV59732671; called by muse, mutect2, varscan2
- CFP | c.747C>T p.T249= | Silent (SNP) | VAF 37/106 reads (35%) | catalogued as rs1301892513, COSV55949836; called by muse, mutect2, varscan2
- COLEC11 | c.546C>T p.D182= | Silent (SNP) | VAF 19/66 reads (29%) | catalogued as rs150837001; called by muse, mutect2, varscan2
- DPY19L1 | c.1488T>C p.F496= | Silent (SNP) | VAF 54/136 reads (40%) | catalogued as COSV60581095; called by muse, mutect2
- FAT2 | c.9774G>A p.G3258= | Silent (SNP) | VAF 28/88 reads (32%) | catalogued as COSV99942449; called by muse, mutect2, varscan2
- H4C6 | c.45C>T p.G15= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as rs201737573, COSV66685431; called by muse, mutect2, varscan2
- LDOC1 | c.213G>A p.T71= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as rs377490828, COSV65159139; called by muse, mutect2, varscan2
- MIS18BP1 | c.2013C>T p.S671= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as rs745934860, COSV60369314; called by muse, mutect2, varscan2
- MYH7 | c.5070C>T p.A1690= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as rs764844610, COSV62516838; called by muse, mutect2, varscan2
- NBL1 | c.201C>T p.S67= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as rs754641009, COSV57029348; called by muse, mutect2, varscan2
- PTCHD3 | c.486C>T p.D162= | Silent (SNP) | VAF 31/85 reads (36%) | catalogued as rs140783092; called by muse, mutect2, varscan2
- SLC16A5 | c.1287C>T p.V429= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as rs535752297, COSV61675454; called by muse, mutect2, varscan2
- TBL1X | c.801G>A p.G267= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as COSV54275627; called by muse, mutect2, varscan2
- TINAGL1 | c.621C>T p.F207= | Silent (SNP) | VAF 17/72 reads (24%) | catalogued as rs138221549; called by muse, mutect2, varscan2
- TMEM156 | c.174G>A p.V58= | Silent (SNP) | VAF 13/47 reads (28%) | catalogued as rs771619623, COSV60744011; called by muse, mutect2, varscan2
- TTN | c.19416G>A p.P6472= (on ENST00000591111; = p.P5545= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 33/88 reads (38%) | catalogued as rs368422028; ClinVar: likely benign; called by muse, mutect2, varscan2
- UBE3B | c.2445G>A p.S815= | Silent (SNP) | VAF 21/73 reads (29%) | catalogued as rs752551850, COSV61072681; called by muse, mutect2, varscan2
- ZNF76 | c.1179C>T p.A393= | Silent (SNP) | VAF 24/84 reads (29%) | catalogued as rs1562134047, COSV57353312; called by muse, mutect2, varscan2
